Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SJ-01A (Primary Tumor).

[page 1 of 6]
Collected
Ordered by

FINAL DIAGNOSIS:

RADICAL CYSTECTOMY WITH BILATERAL PELVIC LYMPH NODE DISSECTION, STUDOR POUCH TO URETHRA:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PERIAORTIC LYMPH NODES (C):

FROZEN SECTION DIAGNOSIS:

- MALIGNANT

FINAL DIAGNOSIS:

- METASTATIC CARCINOMA IDENTIFIED IN FOUR OF TEN LYMPH NODES EXAMINED (4/10)

URINARY BLADDER AND PROSTATE (D):

APICAL URETHRAL MARGIN (DFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETHRAL AND PERIURETHRAL TISSUE

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

URINARY BLADDER:

- DIVERTICULUM EXHIBITING IN SITU (FLAT LESION) AND INVASIVE POORLY DIFFERENTIATED TRANSITIONAL CELL CARCINOMA (3.5 X 3.0 X 1.1 CM), GRADES 3 & 4/4, EXTENDING THROUGH BLADDER DIVERTICULUM WALL INTO PERIVESICAL SOFT TISSUE AND APPROACHING WITHOUT INVOLVING RIGHT URETER
- NO DEFINITIVE LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- RESECTION MARGINS AND PERITONEAL SURFACE, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY
- RANDOM BLADDER MUCOSA, INCLUDING TRIGONE AND BLADDER NECK, SHOWING CHRONIC CYSTITIS WITHOUT EVIDENCE OF UROTHELIAL DYSPLASIA OR MALIGNANCY
- NO MALIGNANCY IDENTIFIED IN THREE PERIVESICAL LYMPH NODES EXAMINED (0/0 RIGHT, 0/3 LEFT, 0/3 TOTAL)

PROSTATE:

- UNILATERAL PROSTATIC ADENOCARCINOMA, GLEASON' S SCORE 6 (3+3), FOCALLY EXTENDING INTO BUT NOT THROUGH CAPSULE AND NOT INVOLVING PERIPROSTATIC SOFT TISSUE
- APICAL, BLADDER NECK AND INKED RADIAL MARGINS, FREE OF TUMOR
- BILATERAL SEMINAL VESICLES, FREE OF TUMOR
- UNINVOLVED PROSTATIC PARENCHYMA SHOWING ACUTE AND CHRONIC INFLAMMATION, FIBROMUSCULAR ADENOMATOUS HYPERPLASIA AND HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN II AND III)
- PROSTATIC URETHRA, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

LEFT PERIAORTIC LYMPH NODES (E):

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Carcinoma, transitional cell NOS
8120/3
Site Bladder NOS
C67.9
J123/26/14

[page 2 of 6]
- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

- METASTATIC CARCINOMA IDENTIFIED IN FOUR OF TEN LYMPH NODES EXAMINED
(4/10)

- METASTATIC CARCINOMA IDENTIFIED IN NINE OF ELEVEN LYMPH NODES EXAMINED, WITH EXTRANODAL EXTENSION (9/11)

- NO METASTATIC CARCINOMA IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

- METASTATIC CARCINOMA IDENTIFIED IN THREE OF 11 LYMPH NODES EXAMINED, WITH EXTRANODAL EXTENSION (3/11)

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

- NO METASTATIC CARCINOMA IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

- NO METASTATIC CARCINOMA IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

- METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE EXAMINED (1/1)

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

PATHOLOGIC TNM STAGE: URINARY BLADDER: pTis,T3bN2MX
PROSTATE: pT2aN0MX

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:
- no high grade atypia or tumor identified

BFS: Left distal ureter:
- no high grade atypia or tumor identified

CFS: Right periaortic lymph nodes:
- malignant

DFS: Urinary bladder and prostate, apical urethral margin:
- no high grade atypia or tumor identified

[page 3 of 6]
Temporary Copy

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter." It consists of a segment of ureter measuring 0.3 cm in length and 0.3 cm in diameter with adjacent fat. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter." It consists of a segment of ureter measuring 0.5 cm in length and 0.3 cm in diameter. The specimen is submitted with adjacent fatty tissue. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Right peri aortic lymph nodes." It consists of a segment of fatty tissue containing lymph nodes measuring 4.5 x 3.5 x 1.5 cm. The largest node measures 1 cm in greatest dimension. The largest node is submitted for frozen section in cassette CFS. The remaining tissue is entirely submitted in two cassettes.

D: The specimen is received fresh from the O.R. and labeled "Urinary bladder & prostate." It consists of bladder with bilateral ureters, prostate and peritoneum measuring overall 24 x 17 x 4.5 cm. The peritoneum measures 21 x 15 x 0.1 cm, and there are adhesions located on its lower aspect. The margins are inked. The apical margin is removed and submitted for frozen section diagnosis. The bladder and the prostate are opened anteriorly. The bladder measures 9.5 x 8 x 3.5 cm. Opening reveals a large diverticulum 5 x 5 x 5 cm located on the right lateral bladder wall 2 cm above the ureterovesical junction. The mouth of the diverticulum measures 2 cm in diameter. The diverticulum is opened and reveals a gray-white, firm tumor located on the base of the diverticulum. The surface of the tumor, 3.5 x 3.0 cm. The tumor invades through the full thickness of the muscularis propria of the thin diverticulum wall, and involves the surrounding soft tissue to a depth of 1.1 cm. The tumor comes within 2 mm of the inked radial margin. There is a 1 cm scarred area of mucosa located between the mouth of the diverticulum and the right ureterovesical junction. The remaining bladder mucosa is intact with a trabecular appearance. The bilateral ureters are opened. Opening reveals a smooth and unremarkable mucosa. The right ureter measures 7 cm in length and 1.4 cm in circumference, and the left ureter measures 7 cm in length and 0.9 cm in circumference. The right ureter is adherent to tumor but the mucosa is uninvolved by tumor grossly. The uninvolved bladder wall measures 0.8 cm in thickness. The prostate measures 5.5 x 4 x 4 cm. The prostatic urethra measures 3 cm in length and 3 cm in circumference. The prostatic urethra is excavated proximally. The verumontanum measures 1.3 x 0.3 x 0.3 cm. The prostate is serially sectioned. Sectioning reveals a well-circumscribed, white-tan nodule located on the apical portion of the prostate measuring 0.5 cm in greatest dimension. The remaining prostatic parenchyma is tan, smooth and unremarkable. Representative sections are submitted in 33 cassettes.

E: The specimen is received in formalin and labeled "Left peri aortic lymph nodes." It consists of a piece of yellow fatty tissue measuring 3 x 2 x 1 cm. The specimen is entirely submitted in one cassette.

F: The specimen is received in formalin and labeled "Right common iliac lymph nodes." It consists of a piece of yellow-tan fatty tissue measuring 6 x 3 x 2.5 cm. There is a large lymph node identified measuring 3 cm in maximum dimension. The specimen is entirely submitted in five cassettes.

G: The specimen is received in formalin and labeled "Presacral lymph nodes." It consists of a piece of yellow-tan fatty tissue measuring 7 x 6 x 3 cm. There are multiple lymph nodes identified. Representative sections are submitted in five cassettes.

[page 4 of 6]
H: The specimen is received in formalin and labeled "Right external iliac lymph nodes." It consists of a piece of yellow-tan fatty tissue measuring 3.5 x 2 x 1 cm. The specimen is entirely submitted in one cassette.

I: The specimen is received in formalin and labeled "Right obturator / hypogastric lymph nodes." It consists of a piece of yellow tan fatty tissue measuring 8 x 6 x 3 cm. There are multiple large lymph nodes identified. The largest node measures 3 cm in maximum dimension. Representative sections are submitted in eight cassettes.

J: The specimen is received in formalin and labeled "Left external iliac lymph nodes." It consists of two pieces of yellow fatty tissue measuring 4 x 3 x 1 cm in aggregate. There is a large lymph node identified measuring 2 cm in maximum dimension. The specimen is entirely submitted in two cassettes.

K: The specimen is received in formalin and labeled "Left common iliac lymph nodes." It consists of yellow fatty tissue measuring 3 x 2 x 1 cm. There are multiple lymph nodes identified. Representative sections are submitted in two cassettes.

L: The specimen is received in formalin and labeled "Left obturator / hypogastric lymph nodes." It consists of a piece of yellow fatty tissue measuring 7 x 6 x 2.5 cm. There are multiple lymph nodes identified. The largest one measures 3 cm in maximum dimension. Representative sections are submitted in four cassettes.

M: The specimen is received in formalin and labeled "Left presciatic lymph nodes." It consists of multiple pieces of yellow fatty tissue measuring 2.5 x 2 x 1 cm in aggregate. The specimen is entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Right presciatic lymph nodes." It consists of multiple pieces of yellow-tan fatty tissue measuring 3 x 2 x 1 cm in aggregate. The specimen is entirely submitted in one cassette.

O: The specimen is received in formalin and labeled "Left proximal ureter." It consists of a segment of ureter measuring 0.6 cm in length and 0.4 cm in diameter. The specimen is serially sectioned and entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Right proximal ureter." It consists of a segment of ureter with surrounding fatty tissue measuring 1 cm in length and 0.5 cm in diameter. The specimen is serially sectioned. Representative sections are submitted in one cassette.

SECTIONS:

AFS:	frozen section, right distal ureter
BFS:	frozen section, left distal ureter
CFS:	frozen section, right periaortic lymph nodes
C1,2:	remaining tissue
DFS:	apical urethral margin
D1:	anterior bladder mucosa
D2:	tumor relationship with ureter
D3,4:	tumor with closest deep margin
D5:	tumor
D6,7:	tumor with adjacent bladder mucosa
D8:	diverticulum wall
D9:	right ureterovesical junction
D10:	dome
D11:	posterior bladder mucosa
D12:	left lateral bladder mucosa
D13:	left ureter vesicle junction
D14:	trigone

[page 5 of 6]
D15: scarring bladder mucosa between diverticulum and right ureterovesical junction
D16: right perivesical fat with possible lymph nodes
D17: left perivesical fat with possible lymph nodes
D18: right seminal vesical
D19: left seminal vesicle
D20: right anterior distal prostate
D21: right posterior distal prostate
D22: left anterior distal prostate
D23: left posterior distal prostate
D24: right posterior midprostate
D25: left posterior midprostate
D26: right anterior 2nd mid prostate
D27: right posterior 2nd midprostate
D28: right anterior 2nd midprostate
D29: left posterior 2nd midprostate
D30: right anterior proximal prostate
D31: right posterior proximal prostate
D32: left anterior proximal prostate
D33: left posterior proximal prostate
E: left periaortic lymph nodes all embedded
F1: right common iliac lymph nodes; largest lymph node bisected
F2-5: multiple lymph nodes
G1-5: presacral lymph nodes representative sections
H: right external iliac lymph nodes all embedded
I1: right obturator/hypogastric lymph nodes; portion of largest lymph node
I2-5: one lymph node, serially sectioned each
I6-8: multiple lymph nodes
J1: left external iliac lymph nodes; largest lymph node
J2: possible lymph node
K1,2: left common iliac lymph nodes representative sections
L1,2: left obturator/hypogastric lymph nodes; multiple lymph nodes
L3: one lymph node serially sectioned
L4: portion of largest lymph node
M: left presciatic lymph nodes all embedded
N: right presciatic lymph nodes all embedded
O: left proximal ureter all embedded
P: right proximal ureter representative sections

MICROSCOPIC DESCRIPTION:

A-C: See final microscopic-diagnosis.

D: Sections of the bladder show an invasive poorly differentiated transitional cell carcinoma, grades 3 & 4/4 (D2-7). A focus of in situ carcinoma is seen adjacent to the invasive tumor (D7). The invasive tumor is characterized by cords, nests and solid sheets of poorly differentiated transitional cells. The tumor extends through the bladder wall into the surrounding perivesical fat. The tumor is adjacent to but does not invade the right ureter (D2). Tumor is present 1 mm from the closest inked radial margin (D4) on the right lateral side. Lymphovascular space invasion is seen (D5). Random sections of the bladder outside the diverticulum show no evidence of urothelial dysplasia or neoplasia but do demonstrate the presence of chronic cystitis. Previous biopsy sites are seen in sections taken from between the right ureterovesical junction and diverticulum.

Sections of the prostate show unilateral (left) prostatic adenocarcinoma (D23,29), Gleason's score 6 (3+3). The tumor is characterized by variably sized glandular structures that infiltrate the stroma. The tumor is confined to the prostate with focal involvement of the capsule, without penetration into periprostatic soft tissue. All margins as well as bilateral seminal vesicles are

[page 6 of 6]
free of tumor. The prostatic urethra is free of urothelial dysplasia and malignancy.

E-P: See final microscopic-diagnosis.

Signed by:

ELECTRONIC SIGNATURE

POST-OPERATIVE DIAGNOSIS:

Same

PRE-OPERATIVE DIAGNOSIS:

Muscle invasive bladder cancer,

ORDERING PHYSICIAN:

Ordering Physician:

Source: NCI Genomic Data Commons file b65137f3-9db8-4b3d-8923-1d05171cf0a3 (TCGA-XF-A9SJ.0093D096-4A35-4543-9FDB-838AE59F0833.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).